Somatic mutation profile of cancer-model specimen HCM-BROD-0958-C56-85B (3D Organoid, passage 7; aliquot HCM-BROD-0958-C56-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-0958-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.8 years (22,920 days).
Specimen HCM-BROD-0958-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0384786-c02d-4a96-8fbb-0fecc467ec91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0958-C56-10A (Blood Derived Normal), aliquot HCM-BROD-0958-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/385267e9-6bab-497b-b769-75c787a46f54

The open-access MAF lists 71 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 12, Nonsense Mutation 4, In Frame Del 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 46/522 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1085308042, CM090865, COSV64291362; ClinVar: pathogenic; called by muse, mutect2
- RB1 | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 6/130 reads (5%) | catalogued as rs1555282775, CM061928, COSV57318349; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.450_452del p.P153del | In Frame Del (DEL) | VAF 128/730 reads (18%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- APOB | c.6804G>C p.Q2268H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV51945563; called by muse, mutect2
- ARFGEF2 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1165877089; called by muse, mutect2, varscan2
- ARID2 | c.3887G>A p.G1296E | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1390067410; called by muse, mutect2, varscan2
- CAPRIN2 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs765204312; called by muse, mutect2
- CARD14 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 78/1068 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs201285077, CM161581; ClinVar: uncertain significance; called by muse, mutect2
- CDK4 | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 25/644 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs863224603; ClinVar: uncertain significance; called by muse, mutect2
- CLK1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs1559328207; called by muse, mutect2
- DIP2C | c.533C>G p.S178W | Missense Mutation (SNP) | VAF 77/817 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55167399; called by muse, mutect2
- ERBB3 | c.1404G>C p.L468F | Missense Mutation (SNP) | VAF 51/567 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99915353; called by muse, mutect2
- GRM3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 74/913 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV64467861; called by muse, mutect2
- HERC1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 28/495 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.254); catalogued as rs942202203, COSV101497115; called by muse, mutect2
- HOXB4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 64/756 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV60179055; called by muse, mutect2
- IQSEC1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 56/584 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs751783194, COSV99831235; called by muse, mutect2
- LAMA3 | c.6094G>A p.E2032K (on ENST00000313654 / NM_198129.4; = p.E423K on NM_000227.6) | Missense Mutation (SNP) | VAF 38/699 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373464847; called by muse, mutect2
- LCOR | c.4552G>A p.G1518R | Missense Mutation (SNP) | VAF 64/548 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs373631781; called by muse, mutect2, varscan2
- MYOF | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190686975; called by muse, mutect2
- NFXL1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs138843661; called by muse, mutect2
- NOTCH1 | c.5387C>T p.P1796L | Missense Mutation (SNP) | VAF 48/550 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs557319054, CM061877; called by muse, mutect2
- PCDHGA2 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 172/1104 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.274); catalogued as rs554157447; called by muse, mutect2, varscan2
- PPP1R1A | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 66/674 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266938174; called by muse, mutect2
- PTH2R | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as rs763353751; called by muse, mutect2
- RAI1 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 88/1129 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs746652874, COSV55390535; called by muse, mutect2
- RB1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57300637; called by muse, mutect2
- SH2B1 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 68/648 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV100450967, COSV100451135; called by mutect2, varscan2
- SNX18 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 61/685 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766025431, COSV57988546; called by muse, mutect2
- TAS2R46 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV67852267, COSV67862863; called by muse, mutect2
- TRIM41 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 123/706 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs78777167; called by muse, mutect2, varscan2
- ZNF705G | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1375914498; called by muse, mutect2, varscan2
- ZNF737 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs572035753, COSV101417619, COSV71200198, COSV71200241; called by muse, mutect2
- ANO10 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 19/230 reads (8%) | called by muse, mutect2
- AP1G1 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2
- ARID1B | c.3657T>A p.S1219R | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CMKLR1 | c.981G>T p.K327N (on ENST00000312143 / NM_001142344.2; = p.K325N on NM_004072.3) | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2
- DNM1 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 58/652 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBXL17 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 87/503 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 70/567 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNQ2 | c.1346G>T p.G449V (on ENST00000359125 / NM_172107.4; = p.G421V on NM_004518.6) | Missense Mutation (SNP) | VAF 84/958 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2
- LCNL1 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 26/587 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- MIPEP | c.1227A>T p.K409N | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MOV10L1 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2
- NKAIN1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 91/537 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NKAIN1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 91/530 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NOTCH4 | c.337A>T p.R113* | Nonsense Mutation (SNP) | VAF 100/1063 reads (9%) | called by muse, mutect2
- PIK3R1 | c.1729_1745+1del | In Frame Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, pindel, varscan2
- PRPF38A | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SEC14L1 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 49/647 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- SLIT3 | c.2173_2175del p.C725del | In Frame Del (DEL) | VAF 130/693 reads (19%) | called by mutect2, pindel, varscan2
- TCP11 | c.283C>T p.H95Y (on ENST00000512012; = p.H33Y on NM_018679.5) | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- TDRD6 | c.2551T>C p.F851L | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2
- TENM3 | c.4972G>C p.A1658P | Missense Mutation (SNP) | VAF 38/515 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2
- TSPYL2 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 60/503 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UNC80 | c.4011C>A p.C1337* | Nonsense Mutation (SNP) | VAF 38/454 reads (8%) | called by muse, mutect2
- UPF3B | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.887); called by muse, mutect2
- WWTR1 | c.1025A>C p.N342T | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- ABCC1 | c.1167C>T p.F389= | Silent (SNP) | VAF 82/880 reads (9%) | catalogued as rs200001462; called by muse, mutect2
- CST5 | c.87C>A p.T29= | Silent (SNP) | VAF 88/547 reads (16%) | catalogued as rs1351658166; called by muse, mutect2, varscan2
- FAT2 | c.9945T>C p.N3315= | Silent (SNP) | VAF 112/566 reads (20%) | catalogued as rs373421914; called by muse, mutect2, varscan2
- FRMPD1 | c.4275C>G p.L1425= | Silent (SNP) | VAF 71/669 reads (11%) | called by muse, mutect2, varscan2
- H1-4 | c.27C>T p.P9= | Silent (SNP) | VAF 44/716 reads (6%) | catalogued as rs765164128; called by muse, mutect2
- KISS1R | c.261G>A p.T87= | Silent (SNP) | VAF 45/515 reads (9%) | catalogued as rs1351947935; called by muse, mutect2
- LEMD2 | c.6C>A p.A2= | Silent (SNP) | VAF 58/706 reads (8%) | catalogued as rs377525478; called by muse, mutect2
- MYH7 | c.4332G>A p.K1444= | Silent (SNP) | VAF 56/684 reads (8%) | catalogued as rs1064797183; ClinVar: uncertain significance; called by muse, mutect2
- PPP1R1A | c.39G>T p.T13= | Silent (SNP) | VAF 66/674 reads (10%) | called by muse, mutect2
- RMDN3 | c.1167C>G p.A389= | Silent (SNP) | VAF 42/534 reads (8%) | called by muse, mutect2
- RYR2 | c.12333C>T p.N4111= | Silent (SNP) | VAF 54/666 reads (8%) | catalogued as rs748716535; ClinVar: uncertain significance; called by muse, mutect2
- SACS | c.11427G>A p.E3809= | Silent (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- ERMARD | c.1521-104C>T | Intron (SNP) | VAF 40/629 reads (6%) | catalogued as rs771511365; called by muse, mutect2
